Somatic mutation profile of tumor specimen TARGET-10-PARYGI-03A (aliquot TARGET-10-PARYGI-03A-01D) from TARGET case TARGET-10-PARYGI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,854 days).
Specimen TARGET-10-PARYGI-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2fd2c91-4e09-490b-97b3-b902777f9b5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARYGI-10A (Blood Derived Normal), aliquot TARGET-10-PARYGI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4f1909a-3f30-4368-84a8-30766376e3e4

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 7, Silent 3, Frame Shift Ins 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNB1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs869312821, CM164914, COSV66099716; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACRBP | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV57522994; called by muse, mutect2, varscan2
- BCL11B | c.1364A>G p.Y455C (on ENST00000357195 / NM_001282237.2; = p.Y384C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733037; called by muse, mutect2, varscan2
- BCL11B | c.1363T>C p.Y455H (on ENST00000357195 / NM_001282237.2; = p.Y384H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733042, COSV61736973; called by muse, mutect2, varscan2
- CDH19 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780796077, COSV50954307; called by muse, mutect2, varscan2
- EARS2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs113593303, COSV71942741; called by muse, mutect2, varscan2
- HELZ2 | c.4777G>A p.D1593N (on ENST00000467148 / NM_001037335.2; = p.D1024N on NM_033405.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1381073929, COSV71295363; called by muse, varscan2
- IMPDH2 | c.667G>C p.A223P | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58707198; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- OR2T6 | c.354G>C p.M118I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV63215655; called by muse, mutect2, varscan2
- RBBP4 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV65131984; called by muse, mutect2, varscan2
- RPL5 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV59872848; called by muse, mutect2, varscan2
- RUNX1T1 | c.225G>A p.T75= (on ENST00000265814 / NM_001198628.1; = p.T48= on NM_004349.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 5/32 reads (16%) | catalogued as rs376480668; called by muse, mutect2, varscan2
- VSIG2 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV52517849; called by muse, mutect2, varscan2
- TECPR1 | c.655_656insTCAAAAAA p.K219Ifs*120 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel
- PREP | c.1731C>T p.R577= (on ENST00000369110; = p.R643= on NM_002726.5) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs149186054; called by muse, mutect2, varscan2
- SIAE | c.285C>T p.F95= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs147638217; called by muse, mutect2, varscan2
- SLC34A3 | c.1122C>T p.G374= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs764008678; called by muse, varscan2
- AHI1 | c.3109+6907T>A | Intron (SNP) | VAF 16/63 reads (25%) | called by muse, varscan2
- AHI1 | c.3109+6838C>T | Intron (SNP) | VAF 26/101 reads (26%) | catalogued as rs1331455415; called by muse, varscan2
- ERAP2 | c.1372-109C>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- MSC | c.-4C>T | 5'UTR (SNP) | VAF 9/59 reads (15%) | catalogued as rs1266457492, COSV57697089; called by muse, mutect2, varscan2
- NCAM1 | c.1826-2767T>C | Intron (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- PDE6B | c.927+38G>A | Intron (SNP) | VAF 13/52 reads (25%) | catalogued as rs747663328; called by muse, mutect2, varscan2
- ZCCHC24 | c.246+1044G>A | Intron (SNP) | VAF 33/133 reads (25%) | catalogued as rs776191773; called by muse, mutect2, varscan2
- ZSCAN18 | c.642+132G>T | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
